Somatic mutation profile of tumor specimen TCGA-DD-A1EG-01A (aliquot TCGA-DD-A1EG-01A-11D-A20W-10) from TCGA case TCGA-DD-A1EG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 77.0 years (28,108 days).
Specimen TCGA-DD-A1EG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f727a511-f2c0-4468-b6c3-2a0e3a1f2302.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EG-10A (Blood Derived Normal), aliquot TCGA-DD-A1EG-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bddedfd-c912-4d69-a55e-a0674cb57d69

The open-access MAF lists 469 somatic variants for this specimen: 404 protein-altering or splice-affecting, 7 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 369, 3'UTR 26, Missense Mutation 26, Intron 21, Silent 7, 5'UTR 5, RNA 3, Splice Site 3, Splice Region 3, 5'Flank 2, Nonsense Mutation 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG2 | c.1545del p.F515Lfs*17 (on ENST00000379869 / NM_001079858.3; = p.F512Lfs*17 on NM_005756.4) | Frame Shift Del (DEL) | VAF 11/126 reads (9%) | catalogued as rs774488954; ClinVar: pathogenic; called by mutect2, pindel
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- ACAP1 | c.1686del p.S563Lfs*49 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as rs34612593; called by pindel, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs757984494, COSV65561192; called by pindel, varscan2
- ADAMTS8 | c.481del p.L161Sfs*84 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV57292254; called by mutect2, pindel
- ALG10B | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 28/304 reads (9%) | catalogued as rs1397842268; called by mutect2, pindel
- ALPK1 | c.3063del p.K1021Nfs*18 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs1159828137; called by pindel, varscan2
- ATE1 | c.289del p.M97Cfs*2 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as COSV56433777; called by pindel, varscan2
- BAHCC1 | c.1684del p.A562Lfs*72 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | catalogued as COSV100312047; called by mutect2, pindel
- BCL10 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs556621354, COSV65354219; called by muse, varscan2
- BMPER | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV51828018; called by mutect2, varscan2
- C2orf78 | c.1779del p.V594Sfs*3 | Frame Shift Del (DEL) | VAF 8/89 reads (9%) | catalogued as rs1558543371; called by mutect2, pindel
- C3orf20 | c.2087A>G p.E696G | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53788233; called by mutect2, varscan2
- CA11 | c.257del p.P86Hfs*2 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV99320704; called by pindel, varscan2
- CASKIN2 | c.1910del p.R637Pfs*9 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV58596256; called by mutect2, pindel
- CASKIN2 | c.846del p.I283Sfs*2 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV58691175; called by mutect2, pindel
- CCP110 | c.31del p.S11Vfs*56 | Frame Shift Del (DEL) | VAF 14/156 reads (9%) | catalogued as rs1567346766; called by mutect2, pindel
- CDK5RAP2 | c.673del p.E225Sfs*2 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV99051631; called by mutect2, pindel
- CELSR2 | c.6059del p.P2020Qfs*14 | Frame Shift Del (DEL) | VAF 11/120 reads (9%) | catalogued as rs1557735024, COSV54767890; called by mutect2, pindel
- CEP295 | c.4463T>A p.F1488Y | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV57355434; called by mutect2, varscan2
- CLCN4 | c.1028del p.G343Afs*34 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as COSV104433009; called by mutect2, pindel
- CLRN3 | c.262del p.T88Lfs*5 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs748191748; called by mutect2, pindel
- COL1A2 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV51963810; called by mutect2, varscan2
- COL5A3 | c.4020del p.R1341Gfs*52 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | catalogued as COSV99318691; called by mutect2, pindel
- CTIF | c.608del p.G203Afs*53 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs1568192695; called by mutect2, pindel
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs1385226543; called by mutect2, pindel, varscan2
- DNAJC22 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV67712715; called by muse, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs1239294263; called by mutect2, pindel
- EGR2 | c.817del p.L273Wfs*8 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as COSV99653919; called by mutect2, pindel
- ELOVL7 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV70918527; called by mutect2, varscan2
- GHITM | c.433A>C p.I145L | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64538759; called by mutect2, varscan2
- GPR139 | c.10del p.T4Rfs*43 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | catalogued as COSV58502346; called by mutect2, pindel
- GRIA1 | c.1500del p.E501Kfs*3 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as COSV53625631; called by mutect2, pindel
- HEY2 | c.561del p.A188Pfs*159 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as rs766155246; called by mutect2, pindel
- HTT | c.9299G>A p.R3100K | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61867204; called by mutect2, varscan2
- IQGAP1 | c.1635del p.N546Mfs*38 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | catalogued as COSV51584243; called by mutect2, pindel
- KANK4 | c.1316G>C p.S439T | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV62988575, COSV62988883; called by mutect2, varscan2
- LIPH | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV56185380; called by mutect2, varscan2
- LIPI | c.362del p.L121Cfs*2 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | catalogued as COSV60712074; called by mutect2, pindel
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 11/123 reads (9%) | catalogued as COSV100540885; called by mutect2, pindel
- LRRIQ1 | c.2267del p.F756Sfs*16 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | catalogued as COSV67828667; called by mutect2, pindel
- MAP1B | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs144088322, COSV57100122; called by mutect2, varscan2
- MAP2K3 | c.822del p.F275Sfs*4 (on ENST00000342679 / NM_145109.3; = p.F246Sfs*4 on NM_002756.4) | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as COSV57566647; called by mutect2, pindel
- MCAT | c.952del p.Q318Sfs*7 | Frame Shift Del (DEL) | VAF 9/107 reads (8%) | catalogued as rs748610263; called by mutect2, pindel
- MTMR7 | c.1633del p.I545Ffs*6 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as COSV51669052; called by mutect2, pindel
- MUC16 | c.6762del p.S2255Pfs*6 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | catalogued as rs776993869, COSV67451814; called by mutect2, pindel
- MYO6 | c.180del p.D61Ifs*5 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | catalogued as COSV100889369; called by mutect2, pindel
- NCAPG | c.695del p.L232* | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | catalogued as COSV52268506; called by mutect2, pindel
- NCOA7 | c.303del p.E102Rfs*23 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as COSV99996597; called by pindel, varscan2
- NR3C1 | c.1583T>G p.L528R | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51545808; called by mutect2, varscan2
- NTRK3 | c.485del p.F162Sfs*41 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV58136067; called by mutect2, pindel
- NUP88 | c.98del p.N33Tfs*24 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs1567581688, COSV99851957; called by mutect2, pindel
- OR51Q1 | c.437del p.T146Mfs*3 | Frame Shift Del (DEL) | VAF 8/144 reads (6%) | catalogued as COSV56180152; called by mutect2, pindel
- OR6S1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57838939; called by muse, varscan2
- OR7A10 | c.655T>G p.S219A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.214); catalogued as COSV50166675; called by mutect2, varscan2
- PCDHGA5 | c.2075A>G p.Y692C | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs774336426; called by mutect2, varscan2
- PHKG1 | c.568del p.Y190Tfs*11 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV51916180; called by mutect2, pindel
- PLIN1 | c.1113del p.A372Lfs*16 | Frame Shift Del (DEL) | VAF 11/163 reads (7%) | catalogued as COSV55584836; called by mutect2, pindel
- PNPLA6 | c.590del p.G197Afs*58 (on ENST00000414982 / NM_001166111.2; = p.G149Afs*58 on NM_006702.5) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV55374216; called by mutect2, pindel
- PRKACA | c.1054del p.*352Rfs*38 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as COSV54115844; called by mutect2, pindel
- PSD | c.676del p.R226Gfs*68 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as rs772089836; called by mutect2, pindel
- RAB33A | c.411del p.H138Mfs*6 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | catalogued as COSV57061436; called by mutect2, pindel
- RIF1 | c.7210del p.I2404Lfs*6 | Frame Shift Del (DEL) | VAF 6/75 reads (8%) | catalogued as COSV54614798; called by mutect2, pindel
- RUFY2 | c.1603del p.I535Yfs*26 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | catalogued as rs894118734; called by pindel, varscan2
- SENP1 | c.250T>C p.S84P | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.54); catalogued as COSV50302005; called by mutect2, varscan2
- SERPINI2 | c.300del p.K100Nfs*20 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as rs780651251; called by mutect2, pindel, varscan2
- SGSH | c.289del p.H97Tfs*167 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as COSV100413254; called by mutect2, pindel
- SLITRK6 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV68391279; called by mutect2, varscan2
- SMARCA2 | c.3984del p.I1329Sfs*55 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | catalogued as COSV56647911; called by mutect2, pindel
- SMARCC2 | c.1912C>G p.H638D | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57222688, COSV57223592; called by mutect2, varscan2
- SOWAHC | c.799del p.L267Wfs*55 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as rs1365852373; called by mutect2, pindel
- SP3 | c.1867del p.C623Vfs*16 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as COSV59467491; called by mutect2, pindel
- SPATA19 | c.502T>C p.*168Rext*61 | Nonstop Mutation (SNP) | VAF 37/107 reads (35%) | catalogued as COSV54484559; called by muse, mutect2, varscan2
- SRFBP1 | c.1273del p.I425Lfs*7 | Frame Shift Del (DEL) | VAF 20/232 reads (9%) | catalogued as rs746594147, COSV59581931; called by mutect2, pindel
- STX8 | c.498del p.K166Nfs*17 | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | catalogued as COSV100111129; called by mutect2, pindel
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | catalogued as rs758822980; called by mutect2, varscan2
- TLE1 | c.427del p.T144Rfs*28 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | catalogued as COSV64686256; called by mutect2, pindel
- TNRC6A | c.4678A>C p.I1560L | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV59368620; called by mutect2, varscan2
- TNS4 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV54187394; called by muse, varscan2
- TOX2 | c.215del p.N72Tfs*10 (on ENST00000358131 / NM_001098798.2; = p.N21Tfs*10 on NM_032883.3) | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | catalogued as COSV57893407; called by mutect2, pindel
- TTLL4 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51438608; called by mutect2, varscan2
- VCAN | c.5140T>C p.W1714R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.269); catalogued as COSV54113555; called by mutect2, varscan2
- WDR49 | c.896C>T p.T299M (on ENST00000308378 / NM_001366158.1; = p.T640M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200695837, COSV57704608; called by mutect2, varscan2
- WNT3A | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs750227757, COSV52729431; called by mutect2, varscan2
- XKR6 | c.424del p.D142Tfs*23 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV52009313; called by mutect2, pindel
- ZFP91 | c.1690del p.D564Ifs*33 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as COSV60157180; called by mutect2, pindel
- ZFYVE27 | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61747214; called by mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 20/144 reads (14%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF407 | c.509del p.P170Rfs*13 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | catalogued as COSV55245772; called by mutect2, pindel
- ZNF597 | c.1011del p.K337Nfs*12 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | catalogued as rs1353303242; called by mutect2, pindel
- ZNF831 | c.2955del p.T986Pfs*79 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV100925896; called by mutect2, pindel
- ZNF862 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs951598863, COSV56225490; called by mutect2, varscan2
- ABL1 | c.2317_2318del p.D773Pfs*18 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by pindel, varscan2
- ADAP1 | c.933del p.F312Sfs*92 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- ADCY6 | c.1501del p.L501Wfs*24 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- AHNAK2 | c.6268del p.Q2090Rfs*11 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, varscan2
- AHNAK2 | c.655del p.T219Rfs*49 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- AHR | c.1741del p.I581Sfs*2 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- ANKRD13B | c.1840del p.E614Sfs*6 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ANKRD27 | c.1840del p.M614Wfs*57 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- ANKRD30A | c.970del p.T324Hfs*73 (on ENST00000611781; = p.T268Hfs*73 on NM_052997.2) | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- APCDD1L | c.1086del p.M363Wfs*121 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel
- ARMCX3 | c.1070del p.L357Wfs*2 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ASPA | c.244del p.M82Cfs*9 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by pindel, varscan2
- ASPM | c.138del p.R46Sfs*22 | Frame Shift Del (DEL) | VAF 8/95 reads (8%) | called by mutect2, pindel
- ATAD5 | c.549del p.S184Pfs*8 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ATG2B | c.818del p.N273Ifs*5 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- ATP2B1 | c.1532del p.L511Cfs*5 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- B4GALT7 | c.825del p.K275Nfs*13 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- BAHCC1 | c.1367del p.G456Afs*10 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- BCAR1 | c.813del p.M272Wfs*41 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- BCL11A | c.2011del p.E671Sfs*85 (on ENST00000335712 / NM_001365609.1; = p.E705Sfs*73 on NM_018014.4) | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- BCL7C | c.412del p.A138Lfs*15 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- BIRC6 | c.2983del p.S995Pfs*28 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- BIRC6 | c.3521del p.L1174Wfs*28 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- BLNK | c.1135del p.S379Pfs*7 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- BLNK | c.83del p.N28Mfs*5 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- BLOC1S5 | c.201del p.K67Nfs*13 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- BMX | c.492del p.T165Pfs*7 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- BRD1 | c.848del p.K283Rfs*33 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- C10orf71 | c.1271del p.N424Tfs*24 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- C16orf96 | c.857del p.P286Qfs*73 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- C17orf107 | c.338del p.P113Qfs*10 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel
- C1orf87 | c.1232del p.P411Lfs*14 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- CADPS2 | c.201del p.R68Efs*25 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- CASP3 | c.686del p.K229Sfs*96 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- CBX2 | c.418del p.H140Tfs*17 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- CD109 | c.971del p.L324* | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- CD5 | c.437del p.P146Rfs*65 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- CDCA7 | c.611del p.K204Sfs*5 (on ENST00000347703 / NM_145810.3; = p.K283Sfs*5 on NM_031942.5) | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- CDK3 | c.469del p.R157Afs*8 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- CEMIP2 | c.4014del p.F1338Lfs*39 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- CEP170B | c.2552del p.P851Lfs*63 (on ENST00000453495; = p.P780Lfs*63 on NM_015005.3) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CEP250 | c.5383del p.E1795Sfs*2 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- CFP | c.1131del p.L378* | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- CHGA | c.1020del p.K340Nfs*13 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- CIC | c.4526del p.L1509* | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- CIR1 | c.240del p.E81Kfs*32 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | called by mutect2, varscan2
- CLCA2 | c.2030del p.F677Sfs*11 | Frame Shift Del (DEL) | VAF 12/127 reads (9%) | called by mutect2, pindel
- CLDN7 | c.29del p.G10Afs*23 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- CMYA5 | c.6561del p.F2187Lfs*16 | Frame Shift Del (DEL) | VAF 13/147 reads (9%) | called by mutect2, pindel
- CNTN6 | c.1525del p.M509Wfs*9 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- COL25A1 | c.652del p.R218Vfs*18 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- COL25A1 | c.438+1del p.X146_splice | Splice Site (DEL) | VAF 4/60 reads (7%) | called by mutect2, pindel
- COL27A1 | c.1768del p.L590Wfs*34 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- COL5A3 | c.98del p.D33Vfs*3 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- COL8A1 | c.1126del p.E376Rfs*5 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- COL9A2 | c.1336del p.V446Wfs*85 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- CPNE6 | c.126del p.C43Afs*15 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- DACT3 | c.1780del p.A594Rfs*10 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- DCLRE1C | c.1517del p.N506Tfs*38 (on ENST00000378278 / NM_001350965.2; = p.N391Tfs*38 on NM_022487.4) | Frame Shift Del (DEL) | VAF 7/85 reads (8%) | called by mutect2, pindel
- DCTN2 | c.827del p.L276Wfs*15 (on ENST00000548249 / NM_001261413.2; = p.L281Wfs*15 on NM_006400.4) | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | called by mutect2, pindel
- DDX54 | c.1954del p.V652Sfs*44 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- DENND4A | c.3177del p.K1059Nfs*29 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- DENND4A | c.2120del p.L707Yfs*74 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | called by mutect2, pindel
- DIAPH1 | c.1907del p.G636Vfs*132 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- DIP2C | c.3098del p.V1033Afs*6 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- DLC1 | c.1485del p.I496Lfs*8 (on ENST00000276297 / NM_001348081.2; = p.I59Lfs*8 on NM_006094.5) | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- DNAJB1 | c.5del p.G2Vfs*71 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- DOCK2 | c.3244del p.I1082Sfs*8 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- DPP3 | c.357del p.K120Rfs*7 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- DRAM2 | c.314del p.G105Dfs*18 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- EFNA2 | c.595del p.L199Sfs*34 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- EIF3M | c.422del p.P141Qfs*25 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel
- ELMO1 | c.1723del p.W575Gfs*17 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- ERAP1 | c.9del p.L4Cfs*21 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ERCC6L | c.3362del p.K1121Rfs*40 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | called by mutect2, pindel
- ERVW-1 | c.149del p.P50Hfs*42 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- EXOSC10 | c.1983del p.F661Lfs*14 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- FAAP100 | c.2457del p.S820Pfs*125 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- FAM133A | c.623del p.K208Rfs*15 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FAM214A | c.2053del p.I685* | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- FAM222B | c.1105del p.Q369Sfs*20 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- FASN | c.5214del p.K1739Rfs*7 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- FIP1L1 | c.639del p.E214Kfs*94 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FKBP15 | c.653del p.F218Sfs*13 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- FREM2 | c.1811del p.F604Sfs*2 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FURIN | c.547del p.Q183Sfs*7 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- FYCO1 | c.674del p.N225Tfs*13 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- FZD10 | c.1677del p.A560Pfs*36 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- G6PC2 | c.203del p.N68Ifs*60 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- GC | c.1281del p.A428Qfs*28 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- GGPS1 | c.735del p.K245Nfs*10 | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel
- GJA4 | c.809del p.G270Afs*25 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | called by mutect2, pindel
- GLYAT | c.99del p.H34Tfs*2 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- GPR158 | c.1763del p.L588Yfs*57 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- GPR84 | c.9del p.N3Kfs*30 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- GRID1 | c.740del p.N247Tfs*12 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- GTF2IRD1 | c.1203del p.C402Afs*8 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- GXYLT1 | c.270del p.S91Lfs*6 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel
- GYPA | c.420del p.E141Kfs*2 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- HARS2 | c.838del p.L280* | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- HIVEP3 | c.3666del p.F1223Sfs*161 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- HMG20B | c.820del p.T274Rfs*170 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- HNRNPUL1 | c.2409del p.T804Lfs*111 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- IGFBPL1 | c.686del p.L229* | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- IGHG3 | c.101del p.E35Nfs*3 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- INO80 | c.640del p.E214Rfs*9 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- INSR | c.1008del p.K337Rfs*6 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- IPPK | c.107del p.K36Sfs*20 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- IRS2 | c.375del p.A126Pfs*75 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- IRX4 | c.28del p.Y10Tfs*8 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ITGB1 | c.161del p.L54Yfs*14 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- ITPKC | c.1121del p.G374Afs*19 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- KCNAB1 | c.75del p.S27Lfs*2 | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | called by pindel, varscan2
- KIAA0100 | c.2770del p.E924Sfs*45 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- KIAA1109 | c.14867del p.G4956Afs*55 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- KMT2B | c.1656del p.K553Nfs*52 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by pindel, varscan2
- KNTC1 | c.4999del p.I1667* | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- KRT18 | c.195del p.I67* | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- LCT | c.3339del p.R1113Sfs*10 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- LGR4 | c.1629del p.T544Lfs*18 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- LIPC | c.1063del p.Q355Sfs*59 | Frame Shift Del (DEL) | VAF 10/141 reads (7%) | called by mutect2, pindel
- LONP1 | c.2155-2del p.X719_splice | Splice Site (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- LPCAT4 | c.483del p.L162Ffs*146 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- LRBA | c.2796del p.A933Pfs*15 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- LRFN2 | c.1695del p.S566Afs*7 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- LRRC4 | c.636del p.N213Ifs*29 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- LTBP4 | c.1435del p.L479Wfs*332 (on ENST00000308370 / NM_001042544.1; = p.L442Wfs*332 on NM_003573.2) | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel
- LYPD5 | c.430del p.D144Mfs*27 (on ENST00000377950 / NM_001031749.3; = p.D101Mfs*27 on NM_182573.2) | Frame Shift Del (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- MAP3K14 | c.581del p.P194Rfs*7 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- ME1 | c.1308del p.F436Lfs*35 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- MED13L | c.5165del p.F1722Sfs*15 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- MEIOC | c.965del p.N322Mfs*2 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- MINK1 | c.3026del p.P1009Lfs*32 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel
- MLLT10 | c.1299del p.F433Lfs*26 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- MLXIPL | c.1571del p.N524Tfs*103 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- MMP19 | c.283del p.T95Pfs*15 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- MMRN1 | c.597del p.K199Nfs*24 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel
- MMS19 | c.1037del p.D346Afs*20 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- MPC1 | c.86del p.G29Afs*3 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel
- MSANTD2 | c.1303del p.L435Sfs*33 (on ENST00000374979 / NM_001308027.2; = p.L383Sfs*33 on NM_024631.4) | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- MYH3 | c.1469del p.F490Sfs*91 | Frame Shift Del (DEL) | VAF 11/113 reads (10%) | called by mutect2, pindel
- MYO9A | c.2948del p.F983Sfs*5 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- NACAD | c.3365del p.P1122Qfs*8 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- NAPSA | c.937-3del | Splice Region (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel
- NBPF1 | c.1457A>G p.H486R | Missense Mutation (SNP) | VAF 84/732 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); called by mutect2, varscan2
- NCBP2 | c.365del p.G122Afs*38 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- NCOR1 | c.6183del p.D2062Ifs*32 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- NEU4 | c.1047del p.R350Gfs*47 (on ENST00000391969 / NM_001167602.3; = p.R362Gfs*47 on NM_080741.4) | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- NEUROD4 | c.297del p.M100Cfs*4 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- NFATC2IP | c.605del p.P202Hfs*18 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- NFKBIB | c.328del p.V110Wfs*152 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- NMRK2 | c.81del p.N28Tfs*4 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- NOL11 | c.588del p.G197Dfs*8 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- NPAS3 | c.2577del p.G860Afs*30 (on ENST00000356141 / NM_001164749.2; = p.G828Afs*30 on NM_022123.3) | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | called by mutect2, pindel
- NPLOC4 | c.922-4del | Splice Region (DEL) | VAF 7/66 reads (11%) | called by pindel, varscan2
- NPTX1 | c.369del p.T124Hfs*58 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- NR2C1 | c.1644del p.R549Dfs*9 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- NSD3 | c.2119del p.C707Vfs*8 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- NSD3 | c.1116del p.I372Mfs*8 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- NT5M | c.561del p.S188Afs*54 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- NUGGC | c.1770del p.T591Rfs*9 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- NUP214 | c.6212del p.G2071Efs*72 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- NUPR2 | c.288del p.T97Pfs*23 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- NWD1 | c.1732del p.L578Sfs*21 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- NWD1 | c.3408del p.F1136Lfs*7 | Frame Shift Del (DEL) | VAF 14/162 reads (9%) | called by mutect2, pindel
- ODR4 | c.891del p.V298Lfs*8 | Frame Shift Del (DEL) | VAF 14/164 reads (9%) | called by mutect2, pindel
- OR1G1 | c.938del p.P313Lfs*? | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- OR5P2 | c.92del p.F31Sfs*2 | Frame Shift Del (DEL) | VAF 4/54 reads (7%) | called by mutect2, pindel
- OR6C70 | c.154del p.Q52Sfs*29 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- OR8B8 | c.910del p.I304Sfs*2 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ORAI1 | c.604del p.L202Sfs*47 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- ORC2 | c.1166del p.F389Sfs*12 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PADI3 | c.1342del p.D448Tfs*28 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- PASD1 | c.2160del p.Q720Hfs*12 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PAXIP1 | c.2151del p.D718Ifs*7 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PCDHGC4 | c.1423del p.C475Afs*12 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- PCED1B | c.559del p.T187Pfs*3 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- PCM1 | c.1725del p.R576Efs*17 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PELI1 | c.154del p.V52* | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PELI3 | c.1370del p.H457Lfs*119 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- PEX1 | c.3803del p.N1268Ifs*13 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel
- PGBD4 | c.1301del p.A434Vfs*32 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- PGM1 | c.1615del p.I540Ffs*5 | Frame Shift Del (DEL) | VAF 21/229 reads (9%) | called by mutect2, pindel
- PIK3C2A | c.1750del p.I584Sfs*5 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- PKD1L3 | c.320del p.P107Qfs*25 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- PLEKHA5 | c.3150del p.E1051Sfs*36 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- PNLIPRP2 | c.1151del p.N384Tfs*43 (on ENST00000611850; = p.N385Tfs*? on NM_005396.5) | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- POLQ | c.6434del p.P2145Qfs*5 | Frame Shift Del (DEL) | VAF 10/109 reads (9%) | called by mutect2, pindel
- PPIL4 | c.161del p.G54Afs*44 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- PPM1F | c.465del p.W155Cfs*35 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- PPP1R15A | c.15del p.A6Hfs*20 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- PPP6R2 | c.253del p.L85* | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- PRAG1 | c.2198del p.L733Wfs*4 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- PRAM1 | c.1981del p.L661Wfs*? | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- PRR3 | c.135del p.M46Wfs*24 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- PRSS53 | c.108del p.K37Sfs*18 | Frame Shift Del (DEL) | VAF 11/121 reads (9%) | called by mutect2, pindel
- PRTG | c.2922del p.A975Pfs*24 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- PSD3 | c.1683del p.S562Afs*55 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | called by mutect2, pindel
- PSKH1 | c.955del p.E319Sfs*18 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- PTAR1 | c.368del p.L123Yfs*8 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel
- PTPRJ | c.1110del p.F370Lfs*6 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- PTPRS | c.779del p.G260Afs*3 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- RAD51D | c.83-4del | Splice Region (DEL) | VAF 9/120 reads (8%) | called by mutect2, pindel
- RAI1 | c.5033del p.K1678Rfs*3 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- RBM6 | c.1300del p.R434Efs*27 | Frame Shift Del (DEL) | VAF 7/85 reads (8%) | called by mutect2, pindel
- RELN | c.4991del p.L1664Cfs*5 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- REV3L | c.9046del p.H3016Ifs*33 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- REXO1 | c.1543del p.A515Pfs*2 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- RING1 | c.1013del p.G338Vfs*38 | Frame Shift Del (DEL) | VAF 6/67 reads (9%) | called by mutect2, pindel
- RNF180 | c.1061del p.P354Lfs*27 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- ROS1 | c.3661del p.S1221Hfs*22 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- RPL7 | c.273del p.F91Lfs*11 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- RPS6KA4 | c.285del p.F97Sfs*22 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- SACS | c.5008del p.Y1670Ifs*21 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SAMD9 | c.1102del p.T368Hfs*31 | Frame Shift Del (DEL) | VAF 7/77 reads (9%) | called by mutect2, pindel
- SAMD9L | c.4121del p.K1374Sfs*3 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- SASH1 | c.2957del p.P986Lfs*36 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- SEC16A | c.4677del p.L1560Cfs*20 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- SEC16A | c.4395del p.N1466Ifs*55 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- SEMA3E | c.273del p.E92Rfs*9 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel
- SEMA4G | c.2312del p.P771Hfs*7 (on ENST00000370250; = p.P776Hfs*7 on NM_017893.3) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- SERPINB2 | c.628del p.T210Lfs*7 | Frame Shift Del (DEL) | VAF 6/71 reads (8%) | called by mutect2, pindel
- SERPINI1 | c.210del p.E71Kfs*11 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SETBP1 | c.4007del p.P1336Qfs*5 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- SETX | c.3974del p.K1325Rfs*4 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by pindel, varscan2
- SI | c.4565del p.G1522Efs*62 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- SIPA1 | c.291del p.L98Cfs*78 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
- SLC17A8 | c.95del p.L32Yfs*17 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel
- SLC22A1 | c.1602del p.A535Qfs*? | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- SLC22A23 | c.2030del p.G677Vfs*7 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- SLC2A13 | c.234del p.A79Pfs*112 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- SLC38A1 | c.695del p.F232Sfs*2 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by pindel, varscan2
- SLC47A2 | c.984del p.V329Sfs*8 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- SLC5A10 | c.1597del p.L533Cfs*2 (on ENST00000395645 / NM_001042450.4; = p.L549Cfs*2 on NM_152351.5) | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- SLCO4A1 | c.26del p.K9Sfs*31 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel
- SMARCA2 | c.2480del p.L827* | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- SNX13 | c.1998del p.H667Tfs*27 | Frame Shift Del (DEL) | VAF 5/62 reads (8%) | called by mutect2, pindel
- SOCS4 | c.1287del p.V430Yfs*20 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- SOX9 | c.934del p.Q312Rfs*71 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- SPEN | c.2328del p.K776Nfs*33 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- SPTBN1 | c.2650del p.L884Wfs*11 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- SRC | c.1442del p.G481Afs*163 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.438del p.G147Vfs*? | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- STIL | c.758del p.K253Rfs*49 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- STXBP2 | c.15del p.L6* | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- SUMF1 | c.181del p.H61Mfs*48 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- SUPT6H | c.4446del p.R1483Gfs*2 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- SYK | c.24del p.D8Efs*27 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- SYNE1 | c.4del p.A2Qfs*16 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- SYNE2 | c.11135del p.N3712Ifs*16 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- SYTL5 | c.1898del p.K633Rfs*21 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- TBCCD1 | c.1257del p.H420Ifs*7 | Frame Shift Del (DEL) | VAF 10/117 reads (9%) | called by mutect2, pindel
- TDRD15 | c.1051del p.S351Hfs*6 | Frame Shift Del (DEL) | VAF 7/77 reads (9%) | called by mutect2, pindel
- TESC | c.544del p.I182Sfs*7 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- TFDP3 | c.545del p.K182Rfs*8 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- TH | c.179del p.P60Qfs*54 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- TLN1 | c.6659del p.K2220Rfs*37 | Frame Shift Del (DEL) | VAF 4/51 reads (8%) | called by mutect2, pindel
- TLR8 | c.2184del p.S729Lfs*10 (on ENST00000218032 / NM_138636.5; = p.S747Lfs*10 on NM_016610.4) | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- TMEM129 | c.242del p.K81Sfs*21 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- TMEM244 | c.336del p.L113* | Frame Shift Del (DEL) | VAF 12/188 reads (6%) | called by mutect2, pindel
- TMPO | c.934del p.S312Hfs*2 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- TMTC3 | c.179del p.P60Lfs*14 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- TNIK | c.1646del p.P549Lfs*48 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel
- TNPO1 | c.592del p.I198* | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- TRIML1 | c.1383del p.C462Afs*3 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- TROAP | c.31del p.L11Sfs*108 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- TRPM4 | c.441del p.S148Afs*130 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- TRPV2 | c.880del p.D294Ifs*5 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- TSHZ2 | c.1991del p.K664Rfs*13 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- TSPAN8 | c.461del p.L154Wfs*22 | Frame Shift Del (DEL) | VAF 7/85 reads (8%) | called by mutect2, pindel
- TSPYL1 | c.442del p.A148Rfs*8 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- TULP4 | c.2647del p.L883Wfs*43 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- UBE2C | c.473del p.N158Tfs*39 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- USP16 | c.1326del p.A443Qfs*25 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | called by mutect2, pindel
- UTP14A | c.1625del p.P542Qfs*17 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- UTP15 | c.1391del p.L464Yfs*7 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- UTY | c.596del p.L199Cfs*40 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- VPS33A | c.82del p.D28Tfs*9 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- VPS35 | c.1834del p.S612Lfs*14 | Frame Shift Del (DEL) | VAF 7/75 reads (9%) | called by mutect2, pindel
- VPS37B | c.694del p.A232Pfs*105 | Frame Shift Del (DEL) | VAF 6/71 reads (8%) | called by mutect2, pindel
- WBP11 | c.1532del p.L511Wfs*24 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- WDR27 | c.1700del p.L567Yfs*8 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- WDR44 | c.569del p.L190* | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- WRN | c.64del p.Q22Rfs*7 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- XPNPEP3 | c.589+1del | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- YME1L1 | c.856del p.T286Pfs*5 (on ENST00000326799 / NM_139312.3; = p.T229Pfs*5 on NM_014263.4) | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- Z83844.2 | c.238del p.S80Afs*29 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ZBTB33 | c.22del p.S8Lfs*12 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- ZC3H6 | c.673del p.I225Sfs*36 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel
- ZC3H7A | c.1646del p.G549Afs*34 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- ZFAND4 | c.1846del p.Q616Sfs*2 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel
- ZFC3H1 | c.3279del p.K1093Nfs*9 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ZGRF1 | c.22-2del p.X8_splice | Splice Site (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- ZMYM1 | c.2731del p.T911Qfs*13 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ZMYM5 | c.1254del p.M418Ifs*9 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- ZNF101 | c.870del p.K290Nfs*97 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- ZNF14 | c.80del p.K27Sfs*6 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- ZNF175 | c.248del p.K83Rfs*40 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | called by mutect2, pindel
- ZNF213 | c.795del p.S266Afs*3 | Frame Shift Del (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- ZNF280A | c.379del p.M127* | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- ZNF331 | c.1385del p.N462Tfs*33 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- ZNF385B | c.1410del p.H471Mfs*25 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- ZNF550 | c.275del p.R92Kfs*20 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- ZNF561 | c.1405del p.R469Efs*14 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- ZNF624 | c.1437del p.A480Pfs*12 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
- ZNF630 | c.1375del p.Y459Mfs*76 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ZNF674 | c.1366del p.I457Lfs*28 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- ZNF675 | c.744del p.D249Ifs*28 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ZNF879 | c.1429del p.I477Ffs*23 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- ZNF91 | c.3452del p.N1151Tfs*11 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ZNF93 | c.648del p.N217Ifs*168 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- ZSCAN2 | c.215del p.G72Dfs*17 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- C3 | c.480C>T p.G160= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV55578987; called by muse, varscan2
- CTTNBP2 | c.3195T>C p.G1065= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- DUOX2 | c.4620C>T p.H1540= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV66533866; called by mutect2, varscan2
- PPP2R5C | c.507G>A p.E169= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV58275209; called by muse, varscan2
- SLC36A3 | c.594C>A p.P198= | Silent (SNP) | VAF 50/195 reads (26%) | catalogued as COSV58857919; called by mutect2, varscan2
- TMPRSS15 | c.195A>G p.T65= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV53046146; called by mutect2, varscan2
- TOMM70 | c.1110C>T p.L370= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs745545730, COSV52524749; called by muse, mutect2, varscan2
- ABHD13 | c.*3310del | 3'UTR (DEL) | VAF 6/54 reads (11%) | catalogued as rs56179812; called by mutect2, pindel
- ACKR2 | c.*773del | 3'UTR (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- ADRB1 | c.*313del | 3'UTR (DEL) | VAF 6/65 reads (9%) | catalogued as rs1345927185; called by pindel, varscan2
- AGAP3 | c.1021-1045del | Intron (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- AQP7 | c.26+36del | Intron (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ATP13A2 | c.347+21del | Intron (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel
- ATP6V1B1 | c.119-22C>T | Intron (SNP) | VAF 12/30 reads (40%) | called by muse, varscan2
- BLOC1S3 | c.*283del | 3'UTR (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel
- CA11 | c.*24del | 3'UTR (DEL) | VAF 6/73 reads (8%) | called by mutect2, pindel
- CAMKK1 | c.*5del | 3'UTR (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel
- CC2D2B | c.37-5del | Intron (DEL) | VAF 14/120 reads (12%) | catalogued as rs1297092413; called by mutect2, pindel, varscan2
- CCNDBP1 | c.250-6del | Intron (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- CFAP46 | c.7117+600del | Intron (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- CISD3 | c.*5del | 3'UTR (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- CPLANE1 | c.*4515del | 3'UTR (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- FGFR2 | c.939+1221del | Intron (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- FOXG1 | c.*903del | 3'UTR (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- FUT2 | c.*220+546del | Intron (DEL) | VAF 12/144 reads (8%) | called by mutect2, pindel
- FUT9 | c.*8605del | 3'UTR (DEL) | VAF 6/71 reads (8%) | called by mutect2, pindel
- FZD1 | c.*575del | 3'UTR (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- HDGF | chr1:156752234 del G | 5'Flank (DEL) | VAF 9/96 reads (9%) | catalogued as rs776848216; called by mutect2, pindel
- HGS | c.537+20del | Intron (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- HMGB1P1 | n.500del | RNA (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- IPO11 | c.2583-12853del | Intron (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- KAZN | c.-10del | 5'UTR (DEL) | VAF 9/104 reads (9%) | called by mutect2, pindel
- KIAA1217 | c.-9del | 5'UTR (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- KNTC1 | c.*18del | 3'UTR (DEL) | VAF 10/90 reads (11%) | catalogued as rs760503972; called by pindel, varscan2
- LGSN | c.-9del | 5'UTR (DEL) | VAF 10/106 reads (9%) | called by mutect2, varscan2
- LSS | c.*251del | 3'UTR (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- MAPKAPK5 | c.36+28del | Intron (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- MBD1 | c.*155C>T | 3'UTR (SNP) | VAF 42/177 reads (24%) | catalogued as COSV54005622; called by mutect2, varscan2
- MIR202 | n.29del | RNA (DEL) | VAF 5/49 reads (10%) | catalogued as rs761013900; called by mutect2, pindel, varscan2
- MIR552 | n.31C>A | RNA (SNP) | VAF 48/168 reads (29%) | called by mutect2, varscan2
- MRPL57 | c.*1849del | 3'UTR (DEL) | VAF 10/111 reads (9%) | called by mutect2, pindel
- MTPN | c.*2215del | 3'UTR (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- PABPC3 | c.*630del | 3'UTR (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- PCNX4 | c.689+957del | Intron (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PCSK5 | c.3523+5320del | Intron (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- PES1 | c.-32del | 5'UTR (DEL) | VAF 3/25 reads (12%) | catalogued as COSV58828453; called by mutect2, pindel
- PURA | c.*1755del | 3'UTR (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- RAP2B | c.*524del | 3'UTR (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- RAP2B | c.*917del | 3'UTR (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- RBBP6 | c.304-9del | Intron (DEL) | VAF 14/107 reads (13%) | called by mutect2, pindel
- REP15 | c.*106del | 3'UTR (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- RPP38 | chr10:15096427 del A | 5'Flank (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- RTN4R | c.23-383del | Intron (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel
- SLITRK2 | chrX:145828369 del T | 3'Flank (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- SMIM27 | c.*1930del | 3'UTR (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- SREK1IP1 | c.278+10del | Intron (DEL) | VAF 14/128 reads (11%) | catalogued as rs112577878, COSV72486181; called by mutect2, pindel
- SSTR2 | c.*79del | 3'UTR (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- TAS2R13 | c.-264del | 5'UTR (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- TMA16 | c.3+22del | Intron (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- TMEM240 | c.*174del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- TTN | c.35375-1077del | Intron (DEL) | VAF 10/105 reads (10%) | catalogued as COSV59972695; called by mutect2, pindel
- TTYH2 | c.*8del | 3'UTR (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- UBR4 | c.7805-136del | Intron (DEL) | VAF 4/32 reads (13%) | catalogued as COSV64396967; called by mutect2, pindel
- UBXN10 | c.*3330del | 3'UTR (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- VKORC1 | c.173+105del | Intron (DEL) | VAF 11/130 reads (8%) | catalogued as COSV100161777; called by mutect2, pindel
